Somatic mutation profile of tumor specimen ALCH-B2A6-TTP1-A (aliquot ALCH-B2A6-TTP1-A-1-0-D-A776-36) from ALCHEMIST case ALCH-B2A6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.8 years (27,313 days).
Specimen ALCH-B2A6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c73f639-ac5b-4f2e-9d62-b4064b56bd69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2A6-NB1-A (Blood Derived Normal), aliquot ALCH-B2A6-NB1-A-1-0-D-A776-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f5476dc-95dd-478f-b58f-aaf170bc8477

The open-access MAF lists 212 somatic variants for this specimen: 132 protein-altering or splice-affecting, 56 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 56, Nonsense Mutation 7, Intron 7, RNA 7, Frame Shift Del 5, 5'UTR 5, Splice Site 3, 3'UTR 3, Splice Region 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 43/281 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AACS | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.398); catalogued as rs769170664, COSV99907769; called by muse, mutect2, varscan2
- ADCY2 | c.3226G>T p.V1076L | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.569); catalogued as COSV100604063; called by muse, mutect2, varscan2
- ADCY8 | c.2075C>T p.S692L | Missense Mutation (SNP) | VAF 49/331 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as rs1042926370, COSV53896436; called by muse, mutect2, varscan2
- ADGRB2 | c.4280C>A p.P1427Q | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.057); catalogued as rs146789434, COSV57070094; called by muse, mutect2, varscan2
- AKAP11 | c.95A>G p.Q32R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.025); catalogued as rs768971572; called by muse, mutect2, varscan2
- AMER3 | c.210del p.Q71Sfs*56 | Frame Shift Del (DEL) | VAF 9/85 reads (11%) | catalogued as COSV58468297; called by mutect2, pindel, varscan2
- CD83 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.751); catalogued as COSV64788929; called by muse, mutect2, varscan2
- CHRNA7 | c.1103G>T p.S368I | Missense Mutation (SNP) | VAF 128/2038 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV60970242; called by muse, mutect2
- CLVS2 | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51569741, COSV99253768; called by muse, mutect2, varscan2
- CNTNAP5 | c.2476G>A p.G826R | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867648836, COSV101443075; called by muse, mutect2, varscan2
- EPX | c.595-2A>G p.X199_splice | Splice Site (SNP) | VAF 128/730 reads (18%) | catalogued as rs1305689535; called by muse, mutect2, varscan2
- FAM222A | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs754400731; called by muse, mutect2, varscan2
- GATB | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1036092694; called by muse, mutect2, varscan2
- GIMAP7 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.172); catalogued as COSV100543619; called by muse, mutect2
- GREB1 | c.4321C>T p.R1441W | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs372022602; called by muse, mutect2, varscan2
- GRIP1 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 45/273 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54014492; called by muse, mutect2, varscan2
- IGHV3-35 | c.122G>C p.C41S | Missense Mutation (SNP) | VAF 43/317 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs375681127; called by muse, mutect2, varscan2
- KLHL4 | c.765G>C p.L255F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100909611; called by muse, mutect2, varscan2
- LIMA1 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs756027943, COSV100372730; called by muse, mutect2
- MAPK4 | c.714G>T p.M238I | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.655); catalogued as rs1316264789; called by muse, varscan2
- MARCO | c.570C>A p.G190= | Splice Region (SNP) | VAF 34/260 reads (13%) | catalogued as COSV59051976; called by muse, mutect2, varscan2
- MDN1 | c.5626G>T p.G1876W | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451841795; called by muse, mutect2, varscan2
- MROH2B | c.647C>A p.T216K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV101270996; called by muse, mutect2, varscan2
- MS4A2 | c.128C>A p.S43* | Nonsense Mutation (SNP) | VAF 30/343 reads (9%) | catalogued as COSV99626957; called by muse, mutect2
- NFIX | c.622G>T p.G208W | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62176756; called by muse, mutect2, varscan2
- NIPSNAP3A | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 50/293 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV101046473; called by muse, mutect2, varscan2
- NME8 | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 72/413 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV99554003; called by muse, mutect2, varscan2
- NPHS1 | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 77/449 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs764181464, CM024136, CM097054; called by muse, mutect2, varscan2
- OBSCN | c.22684T>A p.C7562S | Missense Mutation (SNP) | VAF 15/304 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1018276160; called by muse, mutect2
- OR51E2 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 53/382 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0.125); catalogued as COSV67807187; called by muse, mutect2, varscan2
- OTOP1 | c.1574C>A p.P525Q | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV56396342; called by muse, mutect2, varscan2
- PIK3CD | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 102/698 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63129037; called by muse, mutect2, varscan2
- PLXNB3 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205162516, COSV62795813; called by muse, mutect2
- SLC22A12 | c.1534G>T p.A512S | Missense Mutation (SNP) | VAF 206/1457 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV60571716; called by muse, mutect2, varscan2
- SLC6A5 | c.1749C>G p.I583M | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.45); catalogued as COSV54232608; called by muse, mutect2, varscan2
- STARD3 | c.838G>T p.G280C | Missense Mutation (SNP) | VAF 89/536 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59224448; called by muse, mutect2, varscan2
- SUMF2 | c.595C>A p.Q199K (on ENST00000652303; = p.Q180K on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs767304464, COSV51915198; called by mutect2, varscan2
- TRBV6-1 | c.149C>A p.S50Y | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770660010; called by muse, mutect2, varscan2
- TRRAP | c.4903C>T p.R1635C (on ENST00000359863 / NM_001244580.1; = p.R1617C on NM_003496.3) | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs782392215, COSV62849775; called by muse, mutect2, varscan2
- TTC17 | c.3297A>G p.E1099= | Splice Region (SNP) | VAF 13/125 reads (10%) | catalogued as rs1486866962, COSV50008636; called by muse, mutect2, varscan2
- USP34 | c.1942G>C p.E648Q | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.019); catalogued as COSV68405560; called by muse, mutect2, varscan2
- ZFHX4 | c.4867G>T p.A1623S | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as COSV51440600; called by muse, mutect2, varscan2
- ZNF497 | c.471C>A p.S157R | Missense Mutation (SNP) | VAF 63/486 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV99568307, COSV99568686; called by muse, mutect2, varscan2
- ZNF536 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.73); catalogued as rs762428720, COSV99052767; called by muse, mutect2, varscan2
- ZNF679 | c.624G>T p.R208S | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV55377390; called by muse, mutect2, varscan2
- ABCC8 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AEBP2 | c.1196A>G p.D399G | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AIDA | c.911A>T p.H304L | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2
- AL121899.2 | c.1559T>A p.L520Q | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ANK2 | c.8815A>T p.S2939C | Missense Mutation (SNP) | VAF 47/338 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- AP1B1 | c.1993A>T p.S665C | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AP3B2 | c.1042C>G p.L348V | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- AQP10 | c.106-1G>T p.X36_splice | Splice Site (SNP) | VAF 46/327 reads (14%) | called by muse, mutect2, varscan2
- ARFGEF1 | c.2143A>T p.R715* | Nonsense Mutation (SNP) | VAF 22/120 reads (18%) | called by muse, mutect2, varscan2
- ARFGEF1 | c.1675G>T p.A559S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP6V1H | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 15/161 reads (9%) | called by muse, mutect2
- CCER1 | c.919G>T p.V307F | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- CFAP74 | c.2813C>A p.T938K | Missense Mutation (SNP) | VAF 51/381 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- CFH | c.712A>C p.N238H | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- CHRNA3 | c.546C>A p.Y182* | Nonsense Mutation (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- CNNM4 | c.2312A>C p.H771P | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCDC1 | c.3916C>A p.P1306T (on ENST00000597505 / NM_001367979.1; = p.P413T on NM_020869.3) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- DCX | c.813C>A p.C271* | Nonsense Mutation (SNP) | VAF 102/280 reads (36%) | called by muse, mutect2, varscan2
- DENND2A | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- DKK2 | c.298T>C p.C100R | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DMGDH | c.214G>T p.G72W | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH14 | c.6864A>T p.E2288D (on ENST00000445597; = p.E2941D on NM_001367479.1) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DOCK4 | c.4609G>T p.G1537W | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- DRAXIN | c.928T>A p.C310S | Missense Mutation (SNP) | VAF 68/432 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ERICH3 | c.3118G>T p.A1040S | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- FAM171A1 | c.258G>T p.L86F | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAT4 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 51/372 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCGBP | c.12112G>T p.V4038L | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FDPS | c.558G>T p.Q186H | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FMN2 | c.2827C>T p.P943S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- FTCD | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 113/765 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- FUT8 | c.597+1del | Frame Shift Del (DEL) | VAF 24/120 reads (20%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.1163G>C p.G388A | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GPR52 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRID2 | c.2568C>A p.N856K | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- HAL | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 36/271 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- HAO1 | c.1095G>T p.L365F | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INTS1 | c.347A>C p.E116A | Missense Mutation (SNP) | VAF 55/338 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- INTS2 | c.1164_1183del p.L389Dfs*10 | Frame Shift Del (DEL) | VAF 29/223 reads (13%) | called by mutect2, pindel
- ITGA2 | c.694A>T p.K232* | Nonsense Mutation (SNP) | VAF 58/371 reads (16%) | called by muse, mutect2, varscan2
- JAG2 | c.2833G>T p.A945S | Missense Mutation (SNP) | VAF 110/690 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KAT8 | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 62/471 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA1958 | c.1213A>T p.N405Y | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- KIR3DL1 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 55/393 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- LLGL2 | c.1108G>T p.G370C | Missense Mutation (SNP) | VAF 97/622 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LOXHD1 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC66 | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC9 | c.2305T>A p.W769R | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LUZP1 | c.1204C>T p.L402F | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MED12L | c.1570A>T p.R524W | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYH11 | c.1455G>T p.Q485H | Missense Mutation (SNP) | VAF 129/975 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MYO3B | c.1379del p.N460Ifs*5 | Frame Shift Del (DEL) | VAF 19/123 reads (15%) | called by mutect2, pindel, varscan2
- NEB | c.9160A>T p.I3054F | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- NLRP12 | c.2310G>T p.K770N | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- OR14A16 | c.14C>A p.T5K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- OR2L13 | c.188G>T p.S63I | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- OR4D1 | c.354G>T p.M118I | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- OR51E1 | c.73del p.E25Rfs*19 | Frame Shift Del (DEL) | VAF 27/202 reads (13%) | called by mutect2, pindel, varscan2
- PCDHB13 | c.209G>T p.R70I | Missense Mutation (SNP) | VAF 25/321 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- PKD1L1 | c.5258C>T p.P1753L | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PLXDC2 | c.1061+1G>T p.X354_splice | Splice Site (SNP) | VAF 32/173 reads (18%) | called by muse, mutect2, varscan2
- PRRT4 | c.2530C>A p.P844T | Missense Mutation (SNP) | VAF 50/355 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- PRTN3 | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRUNE2 | c.2305T>A p.W769R | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PUM1 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- R3HDM1 | c.1898G>T p.G633V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); called by muse, mutect2
- RGPD4 | c.1679T>C p.I560T | Missense Mutation (SNP) | VAF 33/321 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ROR1 | c.1768G>T p.G590* | Nonsense Mutation (SNP) | VAF 17/97 reads (18%) | called by muse, mutect2, varscan2
- RTL1 | c.2722C>A p.R908S | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RYR2 | c.9758G>T p.G3253V | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- SAMD9 | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SLC1A6 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); called by muse, mutect2
- SLC30A1 | c.593A>C p.N198T | Missense Mutation (SNP) | VAF 72/526 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SMYD3 | c.502G>T p.A168S (on ENST00000490107 / NM_001375962.1; = p.A109S on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNRPF | c.91G>T p.G31C | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TANC1 | c.2950G>T p.V984L | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- TFAP2B | c.1225G>T p.A409S | Missense Mutation (SNP) | VAF 141/881 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UIMC1 | c.1012C>G p.Q338E | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- UNC79 | c.5293C>A p.P1765T (on ENST00000393151 / NM_001346218.2; = p.P1588T on NM_020818.5) | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- WFIKKN1 | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- YRDC | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZIC1 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 84/480 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF28 | c.1499G>T p.C500F | Missense Mutation (SNP) | VAF 40/347 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF404 | c.1546A>T p.I516F | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- ZNF558 | c.114G>C p.W38C | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ZNF583 | c.1379G>T p.G460V | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, varscan2
- ADAMTS7 | c.4381C>A p.R1461= | Silent (SNP) | VAF 70/532 reads (13%) | called by muse, mutect2, varscan2
- AGT | c.477G>A p.Q159= | Silent (SNP) | VAF 139/984 reads (14%) | called by muse, mutect2, varscan2
- AK7 | c.1056C>T p.I352= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2
- AKNAD1 | c.237T>C p.N79= | Silent (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- ANO1 | c.957G>A p.L319= | Silent (SNP) | VAF 22/170 reads (13%) | called by muse, mutect2, varscan2
- BAHCC1 | c.6075C>T p.A2025= | Silent (SNP) | VAF 50/484 reads (10%) | catalogued as rs782602277; called by muse, mutect2
- CCDC126 | c.375G>T p.V125= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as rs759976381; called by muse, mutect2, varscan2
- CCDC88B | c.2508G>T p.R836= | Silent (SNP) | VAF 80/531 reads (15%) | called by muse, mutect2, varscan2
- CHSY3 | c.325C>T p.L109= | Silent (SNP) | VAF 80/387 reads (21%) | called by muse, mutect2, varscan2
- FAM13A | c.282G>A p.L94= | Silent (SNP) | VAF 33/246 reads (13%) | called by muse, mutect2, varscan2
- FAT1 | c.12816C>T p.S4272= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as rs868429649, COSV71675968; called by muse, mutect2, varscan2
- FLT1 | c.3747G>T p.L1249= | Silent (SNP) | VAF 51/287 reads (18%) | called by muse, mutect2, varscan2
- FMN2 | c.564G>T p.S188= | Silent (SNP) | VAF 86/557 reads (15%) | called by muse, mutect2, varscan2
- GEN1 | c.1734C>T p.S578= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs563563797, COSV58058310; called by muse, mutect2, varscan2
- GUCY2C | c.762C>T p.F254= | Silent (SNP) | VAF 26/187 reads (14%) | called by muse, mutect2, varscan2
- LVRN | c.2373G>T p.A791= | Silent (SNP) | VAF 25/146 reads (17%) | catalogued as rs763520683, COSV63496414; called by muse, mutect2, varscan2
- MAST3 | c.630C>T p.V210= | Silent (SNP) | VAF 99/851 reads (12%) | catalogued as rs1257814583; called by muse, mutect2, varscan2
- MCEE | c.186A>T p.A62= | Silent (SNP) | VAF 53/414 reads (13%) | called by muse, mutect2, varscan2
- MEF2A | c.822C>T p.V274= (on ENST00000557942 / NM_001319206.2; = p.V276= on NM_005587.4 and 8 other RefSeq transcripts) | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- MFAP5 | c.345T>C p.R115= | Silent (SNP) | VAF 28/148 reads (19%) | called by muse, varscan2
- MPPED1 | c.106C>A p.R36= | Silent (SNP) | VAF 110/715 reads (15%) | catalogued as COSV61987046; called by muse, mutect2, varscan2
- MUC12 | c.618T>A p.T206= (on ENST00000379442; = p.T63= on NM_001164462.1) | Silent (SNP) | VAF 32/212 reads (15%) | called by muse, mutect2, varscan2
- MYCT1 | c.285A>T p.R95= | Silent (SNP) | VAF 29/149 reads (19%) | called by muse, mutect2, varscan2
- MYO15A | c.1041G>A p.A347= | Silent (SNP) | VAF 101/775 reads (13%) | catalogued as rs527681283, COSV52753210, COSV52756478; ClinVar: likely benign; called by muse, mutect2, varscan2
- NACC1 | c.399G>T p.L133= | Silent (SNP) | VAF 26/155 reads (17%) | called by muse, mutect2, varscan2
- NAT16 | c.804G>T p.V268= | Silent (SNP) | VAF 103/584 reads (18%) | called by muse, mutect2, varscan2
- OR10H1 | c.120G>T p.L40= | Silent (SNP) | VAF 43/359 reads (12%) | catalogued as COSV58470803; called by muse, varscan2
- OR1K1 | c.606C>A p.T202= | Silent (SNP) | VAF 65/368 reads (18%) | catalogued as COSV52956301; called by muse, mutect2, varscan2
- OR4C46 | c.651G>T p.V217= | Silent (SNP) | VAF 42/207 reads (20%) | called by muse, mutect2, varscan2
- OR8K5 | c.60G>T p.R20= | Silent (SNP) | VAF 16/101 reads (16%) | called by muse, varscan2
- PCDHA3 | c.1911G>T p.L637= | Silent (SNP) | VAF 82/547 reads (15%) | catalogued as rs1554122579; called by muse, mutect2, varscan2
- PFKL | c.687C>T p.F229= | Silent (SNP) | VAF 51/540 reads (9%) | catalogued as COSV62463257; called by muse, mutect2
- PLK1 | c.1515C>T p.L505= | Silent (SNP) | VAF 42/389 reads (11%) | catalogued as rs777991843, COSV55621907; called by muse, mutect2, varscan2
- PRAME | c.243C>T p.L81= | Silent (SNP) | VAF 53/298 reads (18%) | catalogued as rs769568472; called by muse, mutect2, varscan2
- RP1L1 | c.171C>T p.A57= | Silent (SNP) | VAF 89/697 reads (13%) | called by muse, mutect2, varscan2
- RTTN | c.6126G>T p.S2042= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV55347700; called by muse, mutect2, varscan2
- SCFD2 | c.1116G>T p.L372= | Silent (SNP) | VAF 26/171 reads (15%) | called by muse, mutect2, varscan2
- SERPINB4 | c.447C>A p.S149= | Silent (SNP) | VAF 20/188 reads (11%) | called by muse, varscan2
- SLC18A1 | c.1473G>C p.L491= | Silent (SNP) | VAF 20/116 reads (17%) | called by muse, mutect2, varscan2
- SLC25A39 | c.546G>T p.L182= (on ENST00000377095 / NM_001143780.3; = p.L174= on NM_016016.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/158 reads (20%) | called by muse, mutect2, varscan2
- SLC6A2 | c.600C>G p.T200= | Silent (SNP) | VAF 25/145 reads (17%) | called by muse, mutect2, varscan2
- SPATC1 | c.444C>G p.P148= | Silent (SNP) | VAF 88/646 reads (14%) | called by muse, mutect2, varscan2
- SS18L1 | c.114C>T p.Y38= | Silent (SNP) | VAF 78/534 reads (15%) | catalogued as rs756171841; called by muse, varscan2
- TBX21 | c.1134G>A p.K378= | Silent (SNP) | VAF 67/524 reads (13%) | catalogued as rs1201373560; called by muse, mutect2, varscan2
- TET3 | c.1995G>T p.A665= | Silent (SNP) | VAF 15/190 reads (8%) | catalogued as COSV99996286; called by muse, mutect2
- TPH2 | c.924C>G p.P308= | Silent (SNP) | VAF 65/376 reads (17%) | catalogued as COSV100422186; called by muse, mutect2, varscan2
- TPO | c.2220C>T p.D740= | Silent (SNP) | VAF 77/546 reads (14%) | called by muse, mutect2, varscan2
- TRPM5 | c.636G>A p.R212= | Silent (SNP) | VAF 32/139 reads (23%) | called by muse, mutect2
- TTLL8 | c.642C>T p.S214= | Silent (SNP) | VAF 68/410 reads (17%) | called by muse, mutect2, varscan2
- WDFY4 | c.6633G>A p.R2211= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs1426599048; called by muse, mutect2, varscan2
- ZFHX4 | c.4866G>A p.R1622= | Silent (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
- ZGRF1 | c.3399G>A p.G1133= | Silent (SNP) | VAF 15/100 reads (15%) | called by muse, mutect2, varscan2
- ZNF469 | c.5475G>A p.E1825= (on ENST00000437464; = p.E1853= on NM_001367624.2) | Silent (SNP) | VAF 84/542 reads (15%) | called by muse, mutect2, varscan2
- ZNF626 | c.72A>G p.A24= | Silent (SNP) | VAF 48/331 reads (15%) | called by muse, mutect2, varscan2
- ZNF716 | c.969C>A p.P323= | Silent (SNP) | VAF 38/313 reads (12%) | catalogued as COSV70781574; called by muse, mutect2, varscan2
- ZNF729 | c.975T>C p.C325= | Silent (SNP) | VAF 37/252 reads (15%) | called by muse, mutect2, varscan2
- ABHD4 | c.23+172G>T | Intron (SNP) | VAF 40/227 reads (18%) | catalogued as rs752109335; called by muse, varscan2
- AC024651.2 | chr15:97874273 A>T | 5'Flank (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- APOC2 | c.*13C>A | 3'UTR (SNP) | VAF 76/405 reads (19%) | catalogued as rs753384481; called by muse, varscan2
- BRCA1 | c.*657A>G | 3'UTR (SNP) | VAF 6/73 reads (8%) | catalogued as rs1471067431; called by muse, mutect2
- CADM4 | c.-18G>A | 5'UTR (SNP) | VAF 6/23 reads (26%) | catalogued as rs1444321583; called by muse, mutect2, varscan2
- CEP41 | c.*881G>T | 3'UTR (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.9049-34G>T | Intron (SNP) | VAF 72/416 reads (17%) | called by muse, mutect2, varscan2
- ELP4 | c.1146+31767G>T | Intron (SNP) | VAF 4/38 reads (11%) | catalogued as rs1026856764; called by muse, mutect2
- GLRXP3 | n.86C>A | RNA (SNP) | VAF 27/235 reads (11%) | called by muse, mutect2, varscan2
- HBP1 | c.1385+225A>C | Intron (SNP) | VAF 5/40 reads (13%) | catalogued as rs1223456977; called by mutect2, varscan2
- HOXA11 | chr7:27179707 C>T | 3'Flank (SNP) | VAF 89/584 reads (15%) | called by muse, mutect2, varscan2
- LAIR1 | c.35-129G>T | Intron (SNP) | VAF 47/302 reads (16%) | called by muse, mutect2, varscan2
- LMO2 | c.-177C>G | 5'UTR (SNP) | VAF 48/272 reads (18%) | catalogued as rs1426437011; called by muse, mutect2, varscan2
- MID2 | c.-35G>C | 5'UTR (SNP) | VAF 102/273 reads (37%) | called by muse, mutect2, varscan2
- MIR133A2 | n.45G>T | RNA (SNP) | VAF 85/552 reads (15%) | called by muse, mutect2, varscan2
- MIR380 | n.53C>G | RNA (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2
- OR8J3 | c.-2A>C | 5'UTR (SNP) | VAF 8/30 reads (27%) | called by muse, varscan2
- SLC12A1 | c.1215+31G>T | Intron (SNP) | VAF 37/257 reads (14%) | catalogued as rs768154599; called by muse, mutect2, varscan2
- SLC47A1P2 | n.245del | RNA (DEL) | VAF 16/133 reads (12%) | called by mutect2, pindel, varscan2
- SMIM3 | c.-218A>G | 5'UTR (SNP) | VAF 21/167 reads (13%) | called by muse, mutect2, varscan2
- SNORD3A | n.276G>C | RNA (SNP) | VAF 14/81 reads (17%) | catalogued as rs1381012745; called by mutect2, varscan2
- SPATA31C2 | n.1026T>C | RNA (SNP) | VAF 70/441 reads (16%) | called by muse, mutect2, varscan2
- SSPOP | n.9918T>A | RNA (SNP) | VAF 74/570 reads (13%) | called by muse, mutect2, varscan2
- TENM3 | c.511+102083C>G | Intron (SNP) | VAF 125/824 reads (15%) | called by muse, mutect2, varscan2
